Gene-level copy-number profile of tumor specimen TCGA-DX-A6BA-01A from TCGA case TCGA-DX-A6BA, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 53.3 years (19,455 days).
Specimen TCGA-DX-A6BA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.1557ec60-bb88-4941-8c61-a00bc1bec7c6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A6BA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 823 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5737c0aa-bba7-4f56-bb58-292f69910d53

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 14,147; copy number 3: 10,678; copy number 4: 30,155; copy number 5: 1,706; copy number 6: 592; copy number 7: 2,445; copy number 9: 56; copy number 10: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A6BA-01A-11D-A306-01): tumor purity 0.85, ploidy 3.41, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 77 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:86,440,647–87,120,980, 20 genes, copy number 10: KDM3A, CHMP3, RNF103-CHMP3, RNU6-640P, AC015971.1, RNF103, RMND5A, CD8A, CD8B, ANAPC1P1, AC111200.1, RGPD1, WBP1P1, NDUFB4P5, PLGLB1, ANAPC1P2, ANAPC1P2, AC092651.1, AC092651.2, ANAPC1P3.
- chr17:11,598,470–15,341,632, 56 genes, copy number 9 (within-gene range 2–9): DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2, AC084167.1, LINC00670, AC068442.1, MYOCD, MYOCD-AS1, AC005358.1, ARHGAP44, MIR1269B, AC005274.1, AC005277.2, AC005277.1, ELAC2, AC005303.1, LINC02093, HS3ST3A1, MIR548H3, COX10-AS1, AC005304.2, AC005304.1, AC005304.3, CDRT15P1, COX10, SNORA74, CDRT15, AC005224.1, HS3ST3B1, AC005224.3, AC005224.2, AC022816.1, RPS18P12, AC013248.1, AC005863.1, LINC02096, RPL23AP76, AC005772.1, CDRT7, AC005772.2, CDRT8, PMP22, MIR4731, AC005703.5, AC005703.2, AC005703.6, AC005703.1, TEKT3, RNU6-799P.
- chr18:20,946,906–21,111,813, 1 gene, copy number 10 (within-gene range 10–11): ROCK1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
